Somatic mutation profile of tumor specimen TCGA-AA-3549-01A (aliquot TCGA-AA-3549-01A-02D-1953-10) from TCGA case TCGA-AA-3549, project TCGA-COAD (Colon Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Colon, NOS; AJCC pathologic stage: Stage I; Age at diagnosis: 69.6 years (25,415 days).
Specimen TCGA-AA-3549-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 45800593-f8ba-4a61-a3ca-6a4eab1cdcbf.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-AA-3549-10A (Blood Derived Normal), aliquot TCGA-AA-3549-10A-01D-1953-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/bb793d6b-c26a-476a-8326-f954c935df83

The open-access MAF lists 18 somatic variants for this specimen: 15 protein-altering or splice-affecting, 3 silent.
By variant classification: Missense Mutation 14, Silent 3, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCA2 | c.6139C>T p.R2047W (on ENST00000614293; = p.R2017W on NM_001606.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 11/32 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.54); catalogued as rs1275073726, COSV99687573; called by muse, mutect2, varscan2
- ALS2CL | c.161A>G p.H54R | Missense Mutation (SNP) | VAF 22/78 reads (28%) | SIFT tolerated (0.29); PolyPhen benign (0.105); catalogued as rs559406037, COSV100015018; called by muse, mutect2, varscan2
- COL12A1 | c.31G>A p.A11T | Missense Mutation (SNP) | VAF 56/126 reads (44%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.112); catalogued as COSV59393982; called by muse, mutect2, varscan2
- GMEB2 | c.1061C>T p.P354L | Missense Mutation (SNP) | VAF 39/155 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.034); catalogued as rs141199322; called by muse, mutect2, varscan2
- HYDIN | c.14112+2T>C p.X4704_splice | Splice Site (SNP) | VAF 45/258 reads (17%) | catalogued as COSV101125072, COSV101125226; called by muse, mutect2, varscan2
- KLF13 | c.592G>A p.A198T | Missense Mutation (SNP) | VAF 16/33 reads (48%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.72); catalogued as rs1401920578, COSV100207124; called by muse, mutect2, varscan2
- NKX6-2 | c.596G>T p.R199L | Missense Mutation (SNP) | VAF 22/48 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100888337; called by muse, varscan2
- PDE3A | c.805G>C p.E269Q | Missense Mutation (SNP) | VAF 13/37 reads (35%) | SIFT tolerated (0.44); PolyPhen benign (0.444); catalogued as COSV100762091; called by muse, mutect2, varscan2
- PRDM16 | c.1148A>G p.Q383R | Missense Mutation (SNP) | VAF 13/37 reads (35%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.9); catalogued as COSV54604743, COSV99576549; called by muse, mutect2, varscan2
- SCRIB | c.539A>G p.D180G | Missense Mutation (SNP) | VAF 53/154 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.579); catalogued as COSV100253221; called by muse, mutect2, varscan2
- SPEF2 | c.2323T>C p.S775P | Missense Mutation (SNP) | VAF 58/544 reads (11%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100607293; called by muse, mutect2
- SYNDIG1 | c.536G>A p.R179Q | Missense Mutation (SNP) | VAF 15/71 reads (21%) | SIFT tolerated (0.12); PolyPhen benign (0.347); catalogued as rs373605642; called by muse, mutect2, varscan2
- USP34 | c.10511G>A p.C3504Y | Missense Mutation (SNP) | VAF 87/227 reads (38%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0); catalogued as COSV100816017; called by muse, mutect2, varscan2
- WDR13 | c.97C>T p.R33W | Missense Mutation (SNP) | VAF 46/59 reads (78%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV99489321; called by muse, mutect2, varscan2
- ZNF134 | c.1166G>A p.R389Q | Missense Mutation (SNP) | VAF 29/135 reads (21%) | SIFT tolerated (1); PolyPhen benign (0.259); catalogued as rs764224161, COSV68696355; called by muse, mutect2, varscan2
- ABCA3 | c.3198C>T p.C1066= | Silent (SNP) | VAF 81/223 reads (36%) | catalogued as rs200744282, COSV100067894; called by muse, mutect2, varscan2
- CCDC170 | c.1671C>T p.T557= | Silent (SNP) | VAF 90/245 reads (37%) | catalogued as rs563094004, COSV99498241, COSV99498407; called by muse, mutect2, varscan2
- IQSEC3 | c.1476C>T p.I492= (on ENST00000538872 / NM_001170738.2; = p.I189= on NM_015232.1) | Silent (SNP) | VAF 4/20 reads (20%) | catalogued as rs368819066; called by muse, mutect2, varscan2
